Surgical pathology report (de-identified scan), TCGA case TCGA-78-7147, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7147-01A (Primary Tumor).

[REDACTED]

RIGHT UPPER LOBE

Clinical Details:

Right upper lobectomy for FNA Bx proven adenocarcinoma.

Two specimens received:

1: RIGHT UPPER LOBE

Macroscopy:

The specimen is labelled "right upper lobe" and consists of a lobe of lung measuring approximately 165 x 100 x 55 mm in the inflated state. There are two staple lines present on the medial aspect of the specimen. Both of these are excised and the resultant margins inked with black ink. The lateral pleural surface is puckered over an area measuring approximately 15 x 6 mm. On sectioning through the lung parenchyma there is a firm cream nodule present deep to this puckering which measures 45 mm in greatest dimension. This lesion appears to abut the overlying pleura and is 21 mm from the nearest parenchymal resection margin. No endobronchial component of the lesion is identified macroscopically. The adjacent lung parenchyma appears unremarkable. [RS taken through bronchial and vascular resection margins-1A; peribronchial lymph node-1B; tumour with overlying pleural surface 1C-1E; parenchymal resection margin-1F; section through adjacent uninvolved lung-1G.]

Microscopy:

Sections show a moderately differentiated adenocarcinoma. The lesion is subpleural and the tumour invades into but not through the visceral pleura. There is no blood vessel invasion and no lymphatic permeation is seen. No perineural permeation is identified. The lesion is well clear of the bronchial and the surgical resection margin. A peribronchial lymph node metastasis of adenocarcinoma is seen. Abutting the carcinoma in block 1 F is a carcinoid tumourlet. The adjacent lung shows very mild centriacinar emphysema. The bronchial resection margin shows mild active chronic inflammation and squamous metaplasia.

2: HILAR LYMPH NODE

Macroscopy:

The specimen is labelled "hilar lymph node" and consists of two pieces of dark tan tissue measuring in aggregate 16 x 8 x 3 mm. [BIT-2A.] [REDACTED]

Microscopy:

Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

Summary:

Right upper lobe lung and hilar lymph nodes:

- 1: Moderately differentiated adenocarcinoma; 45 mm in maximal dimension.
- 2: No blood vessel, lymphatic or perineural invasion present.
- 3: Visceral pleural invasion identified; clear of bronchial and surgical margin.
- 4: Peribronchial lymph node metastasis.
- 5: T2N1MX
- 6: Adjacent tumourlet.

T-28000 M-81403 P1-03000

[REDACTED]

Copies

[REDACTED]

Source: NCI Genomic Data Commons file ed886d29-aaf0-401b-a63b-41b8857e9525 (TCGA-78-7147.0F5AD63E-A072-4F02-8F88-1D75FABD3A4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).